Gene-level copy-number profile of tumor specimen TCGA-D7-A6F0-01A from TCGA case TCGA-D7-A6F0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 79.2 years (28,923 days).
Specimen TCGA-D7-A6F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.65b89e38-194f-40b0-a078-94b754c6ad20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A6F0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a6c84569-eaeb-40b0-9669-e6ff04efb7c3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 18; copy number 2: 4,781; copy number 3: 8,113; copy number 4: 18,235; copy number 5: 15,467; copy number 6: 4,376; copy number 7: 3,582; copy number 8: 3,568; copy number 9: 466; copy number 10: 197; copy number 11: 301; copy number 12: 410; copy number 13: 2; copy number 14: 162; copy number 15: 7; copy number 17: 37; copy number 24: 28; copy number 52: 18; copy number 65: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A6F0-01A-11D-A31K-01): tumor purity 0.56, ploidy 4.6, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,586,626–140,683,888, 2 genes: MIR7157, COPRSP1.
- chr5:101,816,475–101,976,798, 2 genes: OR7H2P, AC117525.1.
- chr9:9,442,060–9,803,784, 2 genes: RN7SL5P, AL513422.1.
- chr9:72,299,720–72,471,076, 5 genes: RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1.
- chr10:87,341,685–88,584,530, 25 genes (within-gene range 0–4): LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr12:85,567,878–85,568,239, 1 gene: AC126471.1.
- chr21:46,598,604–46,665,124, 3 genes: S100B, PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,637 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,980,181–12,221,271, 15 genes, copy number 9 (within-gene range 5–9): MFN2, AL096840.1, MIIP, Y_RNA, MIR6729, RN7SL649P, TNFRSF8, RNU6-777P, RPL23AP89, AL357835.1, MIR7846, TNFRSF1B, MIR4632, RPL10P17, SNORA70.
- chr3:11,745–551,657, 9 genes, copy number 14: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1.
- chr3:617,789–618,314, 1 gene, copy number 9: RPSAP32.
- chr3:126,083,659–127,390,670, 34 genes, copy number 9: AC079848.1, ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1, CHST13, C3orf22, RNA5SP138, TXNRD3, AC024558.1, NUP210P1, AC078867.1, CHCHD6, RCC2P4, AC011199.1, PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016.
- chr3:133,932,701–145,963,623, 181 genes, copy number 9–14 (within-gene range 5–14) (broad region; genes not listed).
- chr3:146,391,363–146,606,216, 7 genes, copy number 15 (within-gene range 7–15): AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:159,711,852–175,810,548, 187 genes, copy number 9–10 (within-gene range 1–12) (broad region; genes not listed).
- chr3:175,234,861–194,260,720, 346 genes, copy number 9 (broad region; genes not listed).
- chr8:2,923,568–6,257,537, 24 genes, copy number 9 (within-gene range 8–9): AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1, AC009435.1.
- chr11:67,317,871–67,805,336, 43 genes, copy number 11 (within-gene range 5–11): RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1, CDK2AP2, CABP2, AP001184.1, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P.
- chr12:31,280,584–31,369,301, 5 genes, copy number 9 (within-gene range 5–9): SINHCAF, AC024940.3, FLJ13224, LINC02387, U6.
- chr12:31,396,390–31,396,501, 1 gene, copy number 9: RNU6-618P.
- chr14:35,447,003–35,537,054, 4 genes, copy number 10–13: AL133163.3, RPS3AP4, KRT18P6, INSM2.
- chr17:3,636,459–3,696,240, 7 genes, copy number 10: CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr17:3,721,628–3,726,699, 2 genes, copy number 10: AC116914.2, HASPIN.
- chr19:29,775,504–31,466,431, 27 genes, copy number 52–65: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1.
- chr20:10,006,381–10,368,776, 1 gene, copy number 11 (within-gene range 5–11): SNAP25-AS1.
- chr20:10,172,522–11,029,455, 21 genes, copy number 9–11: AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1.
- chr22:15,290,718–30,326,947, 722 genes, copy number 11–24 (within-gene range 6–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
